Somatic mutation profile of tumor specimen TCGA-BR-6852-01A (aliquot TCGA-BR-6852-01A-11D-1882-08) from TCGA case TCGA-BR-6852, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 64.3 years (23,469 days).
Specimen TCGA-BR-6852-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17bff4d8-6167-40b1-91b5-420d09a3deab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-6852-10A (Blood Derived Normal), aliquot TCGA-BR-6852-10A-01D-1882-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ef4d4c0-cab2-404c-9c48-0a2a06f8c096

The open-access MAF lists 1,229 somatic variants for this specimen: 938 protein-altering or splice-affecting, 270 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 623, Silent 270, Frame Shift Del 212, Frame Shift Ins 38, Nonsense Mutation 32, Splice Site 16, Splice Region 10, RNA 9, In Frame Del 7, Intron 6, 3'UTR 4, 3'Flank 2.

Variants (750 of 1,229; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs61750200, CM980004; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRCA2 | c.5351del p.N1784Tfs*7 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | catalogued as rs80359507; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel
- CPAMD8 | c.2352del p.R785Efs*32 (on ENST00000651564; = p.R738Efs*32 on NM_015692.5) | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DDX3X | c.741C>T p.G247= (on ENST00000399959; = p.G248= on NM_001356.5) | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs1569238002, COSV67863076; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 25/203 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLNA | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28935469, CM030665, COSV61043496; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FOXG1 | c.770T>C p.L257P | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555321353; ClinVar: pathogenic; called by muse, mutect2
- MECP2 | c.710dup p.G238Wfs*21 | Frame Shift Ins (INS) | VAF 30/208 reads (14%) | catalogued as rs61749743; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 28/160 reads (18%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MYO15A | c.1185del p.E396Rfs*48 | Frame Shift Del (DEL) | VAF 11/108 reads (10%) | catalogued as rs772536599; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- NPC1 | c.2978del p.G993Efs*4 | Frame Shift Del (DEL) | VAF 33/217 reads (15%) | catalogued as rs775915490, CD053590, COSV99342140; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PALB2 | c.839del p.N280Tfs*8 | Frame Shift Del (DEL) | VAF 19/116 reads (16%) | catalogued as rs1555461597; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC16A1 | c.41dup p.D15Rfs*34 | Frame Shift Ins (INS) | VAF 10/52 reads (19%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, varscan2
- SPATA5 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs567175477, CM159198, COSV56776347; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TPO | c.2421del p.C808Afs*24 | Frame Shift Del (DEL) | VAF 15/72 reads (21%) | catalogued as rs760307139, COSV100220194; ClinVar: pathogenic; called by mutect2, pindel
- TRIP12 | c.4784G>A p.R1595Q | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs1553602821, COSV52260381; ClinVar: pathogenic; called by muse, mutect2, varscan2
- UROS | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121908014, CM920707, COSV64229563; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 16/139 reads (12%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, pindel
- AAK1 | c.1139G>T p.G380V | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65907396; called by muse, mutect2, varscan2
- ABCA13 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70029810; called by muse, mutect2, varscan2
- ABCB4 | c.1130T>A p.I377N | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55935662; called by muse, mutect2, varscan2
- ABCC11 | c.3916G>T p.A1306S | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV62323286, COSV62325186; called by muse, mutect2, varscan2
- ABHD16B | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748828615, COSV53862071; called by muse, mutect2
- ABRAXAS1 | c.407C>T p.T136I | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58948915; called by muse, mutect2, varscan2
- ABTB2 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs780494894, COSV54388652; called by muse, mutect2, varscan2
- ACAD11 | c.1534G>T p.A512S | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV51442590; called by muse, mutect2, varscan2
- ACMSD | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as rs199569492, COSV51605508, COSV51606977; called by muse, mutect2, varscan2
- ACOX3 | c.1020G>T p.E340D | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV62712109; called by muse, mutect2, varscan2
- ACOXL | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV61325203; called by muse, mutect2, varscan2
- ACTN1 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV51992257; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 33/108 reads (31%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADCY1 | c.2279C>T p.T760I | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV52035062; called by muse, mutect2
- ADNP2 | c.971del p.P324Lfs*8 | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | catalogued as rs772825390; called by mutect2, varscan2
- AFAP1 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs769468121, COSV61795736; called by muse, mutect2, varscan2
- AFDN | c.509del p.K170Rfs*53 | Frame Shift Del (DEL) | VAF 26/110 reads (24%) | catalogued as rs1431558072; called by mutect2, varscan2
- AFDN | c.996G>A p.W332* | Nonsense Mutation (SNP) | VAF 7/172 reads (4%) | catalogued as COSV60045344; called by muse, mutect2
- AGPAT4 | c.1010C>T p.T337M | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.92); catalogued as COSV57245133; called by muse, mutect2, varscan2
- AIFM3 | c.720G>T p.K240N | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV58999614; called by muse, mutect2, varscan2
- AKAP17A | c.430del p.E144Sfs*18 | Frame Shift Del (DEL) | VAF 42/332 reads (13%) | catalogued as COSV58308392; called by mutect2, pindel, varscan2
- AKAP6 | c.6933A>C p.E2311D | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); catalogued as COSV99797692; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKR1C3 | c.378G>T p.E126D | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV65910513, COSV65910531; called by muse, mutect2, varscan2
- AL162417.1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as rs766608683, COSV64404439; called by muse, mutect2, varscan2
- ALAS2 | c.638+2T>C p.X213_splice | Splice Site (SNP) | VAF 14/72 reads (19%) | catalogued as COSV58190742; called by muse, varscan2
- ALDOC | c.919C>A p.Q307K | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1335646776, COSV52024574; called by muse, mutect2, varscan2
- ALKBH4 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV52961028; called by muse, mutect2, varscan2
- ALPK1 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 16/190 reads (8%) | catalogued as COSV51585360; called by muse, mutect2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 64/444 reads (14%) | catalogued as rs1341338515; called by mutect2, pindel, varscan2
- ANGPTL5 | c.1130T>C p.M377T | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57533160; called by muse, varscan2
- ANK3 | c.12875A>G p.H4292R (on ENST00000280772 / NM_001320874.2; = p.H916R on NM_001149.3) | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55059376; called by muse, mutect2
- ANK3 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs868365286, COSV55044904; called by muse, mutect2, varscan2
- ANKRD12 | c.4978C>T p.P1660S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.003); catalogued as rs765291091, COSV50825809; called by muse, mutect2, varscan2
- ANO7 | c.2783C>T p.A928V (on ENST00000274979; = p.A874V on NM_001370694.2) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV51472161; called by mutect2, varscan2
- ANOS1 | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV52920288, COSV52926406; called by muse, mutect2, varscan2
- APBA1 | c.2493G>T p.Q831H | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55228450; called by muse, mutect2, varscan2
- ARFGEF2 | c.1766C>T p.T589I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1488096399, COSV64212450; called by muse, mutect2, varscan2
- ARHGAP26 | c.1994del p.P665Rfs*135 | Frame Shift Del (DEL) | VAF 19/121 reads (16%) | catalogued as rs1298538973; called by mutect2, pindel, varscan2
- ARHGEF4 | c.58T>C p.F20L | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV58122809; called by muse, mutect2, varscan2
- ARHGEF40 | c.2209del p.A737Pfs*3 | Frame Shift Del (DEL) | VAF 12/110 reads (11%) | catalogued as rs749402223; called by mutect2, pindel
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 37/158 reads (23%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID2 | c.3546del p.F1182Lfs*6 | Frame Shift Del (DEL) | VAF 14/97 reads (14%) | catalogued as COSV57613825; called by mutect2, varscan2
- ARMT1 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV66178583; called by muse, mutect2, varscan2
- ARVCF | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as rs1179130091, COSV54267036; called by muse, mutect2
- ASCC3 | c.5065C>T p.R1689C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs527410635, COSV64975373; called by mutect2, varscan2
- ASL | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as rs768087423, COSV59188469; called by muse, mutect2, varscan2
- ASS1 | c.722G>A p.G241D | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as COSV61689473; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 37/155 reads (24%) | catalogued as rs746676748; called by mutect2, varscan2
- ATG2A | c.2204A>C p.Q735P | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV65966952; called by muse, mutect2, varscan2
- ATP10A | c.3566C>A p.P1189H | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63517670, COSV63518306; called by muse, mutect2, varscan2
- ATP13A1 | c.3002G>A p.S1001N | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV52286296; called by muse, mutect2, varscan2
- ATP1A4 | c.1461G>T p.E487D | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63626597; called by muse, mutect2
- ATP2A3 | c.2695A>G p.M899V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.454); catalogued as COSV59229556; called by muse, mutect2, varscan2
- ATP2B4 | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58178229; called by muse, varscan2
- ATP9A | c.1378G>A p.V460M | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs199887924, COSV58766016; called by muse, mutect2, varscan2
- ATRX | c.2239A>G p.S747G | Missense Mutation (SNP) | VAF 66/341 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV64876953; called by muse, mutect2, varscan2
- AVPR1B | c.918G>A p.W306* | Nonsense Mutation (SNP) | VAF 23/121 reads (19%) | catalogued as COSV65638123; called by muse, mutect2, varscan2
- B9D2 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.576); catalogued as COSV54684092; called by muse, mutect2, varscan2
- BAIAP2 | c.1112T>C p.L371P | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV58335666; called by muse, mutect2, varscan2
- BAK1 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs765284813, COSV62349595; called by muse, mutect2, varscan2
- BARHL1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.019); catalogued as rs1388115023, COSV55037727; called by muse, mutect2
- BCL7C | c.617dup p.L207Tfs*10 | Frame Shift Ins (INS) | VAF 48/242 reads (20%) | catalogued as rs754078059; called by mutect2, varscan2
- BCS1L | c.1082T>C p.L361P | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV55307543; called by muse, mutect2, varscan2
- BICC1 | c.1083G>T p.K361N | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54063917; called by muse, mutect2, varscan2
- BIRC5 | c.421A>G p.M141V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1486872997, COSV56956518; called by muse, mutect2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 12/77 reads (16%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BMT2 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376187358; called by muse, mutect2, varscan2
- BRCA2 | c.7633G>A p.V2545I | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as rs80358990, COSV66454265; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | catalogued as rs763134487; called by mutect2, varscan2
- BROX | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV60663947; called by muse, mutect2, varscan2
- BROX | c.563A>G p.Q188R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.716); catalogued as COSV61799327; called by muse, mutect2
- BRPF1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs755029735, COSV57403970; called by muse, mutect2, varscan2
- BRPF1 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs1167611082, COSV57405048; called by muse, mutect2, varscan2
- BSN | c.2146C>T p.P716S | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0.185); catalogued as COSV56513651; called by muse, mutect2, varscan2
- BTN3A3 | c.1309A>G p.T437A | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as COSV55072104; called by muse, mutect2, varscan2
- C16orf71 | c.16A>G p.K6E | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV58509049; called by muse, mutect2
- C1GALT1C1 | c.810T>G p.C270W | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58974211; called by muse, mutect2, varscan2
- C1orf105 | c.319T>G p.F107V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as COSV62959363; called by muse, mutect2, varscan2
- C2CD2L | c.1088A>G p.E363G | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV60884056; called by muse, mutect2, varscan2
- C3 | c.3096G>T p.E1032D | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV55573518; called by muse, mutect2, varscan2
- C6 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as rs748385522, COSV54710688; called by muse, mutect2, varscan2
- C6orf62 | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.201); catalogued as rs746559542, COSV65290506; called by muse, mutect2, varscan2
- CACNA1E | c.2759G>A p.R920H | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs377338098; called by muse, mutect2
- CACNG3 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50064973; called by muse, mutect2, varscan2
- CALB1 | c.421A>G p.T141A | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV55367779; called by muse, mutect2, varscan2
- CALM1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.042); catalogued as COSV63662693; called by muse, mutect2, varscan2
- CAMSAP3 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs184572684, COSV50335370; called by muse, mutect2, varscan2
- CAMTA2 | c.1081G>A p.G361S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.994); catalogued as COSV61835119; called by muse, mutect2, varscan2
- CAND1 | c.1091G>T p.R364M | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73338596; called by muse, mutect2, varscan2
- CAND1 | c.2677C>T p.P893S | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763788810, COSV73389625; called by muse, mutect2, varscan2
- CANX | c.1406T>C p.V469A | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV56004294; called by muse, varscan2
- CAPN6 | c.986A>C p.D329A | Missense Mutation (SNP) | VAF 56/546 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60695125; called by muse, mutect2, varscan2
- CARS2 | c.657G>A p.A219= | Splice Region (SNP) | VAF 19/97 reads (20%) | catalogued as rs375938059, COSV99959725; ClinVar: likely benign; called by muse, mutect2, varscan2
- CASKIN2 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs557204985, COSV58595938; called by muse, mutect2, varscan2
- CASP8 | c.337A>C p.S113R (on ENST00000432109 / NM_033355.3; = p.S145R on NM_001228.4) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV51851315; called by muse, mutect2, varscan2
- CCDC13 | c.1371+2T>C p.X457_splice | Splice Site (SNP) | VAF 33/177 reads (19%) | catalogued as COSV59606998; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC83 | c.335del p.N112Tfs*2 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs763412848; called by mutect2, pindel, varscan2
- CCDC87 | c.551G>T p.R184M | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV59579166; called by muse, mutect2, varscan2
- CCM2L | c.141del p.D48Tfs*27 | Frame Shift Del (DEL) | VAF 20/114 reads (18%) | catalogued as COSV52949350; called by mutect2, pindel, varscan2
- CCNA1 | c.746A>T p.D249V | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99714217; called by mutect2, varscan2
- CCNO | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV99248057; called by muse, mutect2, varscan2
- CD1D | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs1245473930, COSV63808690; called by muse, mutect2, varscan2
- CD36 | c.123A>C p.Q41H | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV59213426; called by muse, mutect2, varscan2
- CDAN1 | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 23/124 reads (19%) | catalogued as COSV62332108; called by muse, mutect2, varscan2
- CDH10 | c.1003-1G>A p.X335_splice | Splice Site (SNP) | VAF 16/61 reads (26%) | catalogued as COSV52581877; called by muse, mutect2, varscan2
- CDH16 | c.1686del p.K563Sfs*22 | Frame Shift Del (DEL) | VAF 19/120 reads (16%) | catalogued as rs776664434; called by mutect2, pindel, varscan2
- CDH20 | c.1422G>T p.Q474H | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV53010207; called by muse, mutect2
- CDK5R1 | c.173T>C p.V58A | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1443682931, COSV55578874; called by muse, mutect2, varscan2
- CDR2 | c.614T>C p.L205S | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51676330; called by muse, mutect2, varscan2
- CELF4 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as COSV58450625; called by muse, mutect2, varscan2
- CEMIP2 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV65487355, COSV65489742; called by muse, mutect2, varscan2
- CENPJ | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.039); catalogued as COSV67883459; called by muse, mutect2, varscan2
- CEP112 | c.1980+1G>A p.X660_splice | Splice Site (SNP) | VAF 8/60 reads (13%) | catalogued as rs772133327, COSV67139861; called by muse, mutect2, varscan2
- CES3 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs763361117, COSV57593631; called by muse, mutect2, varscan2
- CETP | c.785T>C p.L262P | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as CD095244, COSV52362351; called by muse, mutect2, varscan2
- CFAP161 | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs756224699, COSV54429367; called by muse, mutect2, varscan2
- CFAP45 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); catalogued as rs776543202, COSV63649147; called by muse, mutect2, varscan2
- CHD7 | c.6630G>T p.E2210D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.012); catalogued as COSV71110831, COSV71110985; called by muse, mutect2
- CHD9 | c.1705A>T p.R569W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV68298293; called by muse, mutect2
- CHKA | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1373308573, COSV55835645; called by muse, mutect2, varscan2
- CHN1 | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as rs759861126, COSV55033705; called by muse, mutect2, varscan2
- CHN1 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1423263261, COSV55033727; called by muse, mutect2, varscan2
- CHODL | c.158G>T p.S53I | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV54732805; called by muse, mutect2, varscan2
- CHPF2 | c.418del p.A140Pfs*68 | Frame Shift Del (DEL) | VAF 18/168 reads (11%) | catalogued as COSV50398300; called by mutect2, pindel, varscan2
- CHRND | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766721840, COSV51319555, COSV51321452; called by muse, mutect2, varscan2
- CHST6 | c.995C>A p.A332D | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60000216; called by muse, mutect2, varscan2
- CIC | c.3347dup p.S1117Kfs*34 | Frame Shift Ins (INS) | VAF 14/84 reads (17%) | catalogued as rs761345552; called by mutect2, varscan2
- CIDEB | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs146066890; called by muse, mutect2, varscan2
- CLCN2 | c.2552G>A p.R851Q | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.929); catalogued as rs149460784; called by muse, mutect2, varscan2
- CLCN3 | c.2263C>A p.L755I | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.602); catalogued as COSV61627166, COSV61627952; called by muse, mutect2, varscan2
- CLN8 | c.694A>C p.T232P | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as rs1015504418, COSV58670551; called by muse, mutect2, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 31/170 reads (18%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel, varscan2
- COL27A1 | c.3833C>T p.P1278L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.34); catalogued as COSV61926358; called by muse, mutect2
- COL28A1 | c.2691del p.V898Wfs*18 | Frame Shift Del (DEL) | VAF 16/73 reads (22%) | catalogued as rs766010947; called by mutect2, pindel, varscan2
- COL4A1 | c.4832C>T p.A1611V | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as rs775233741, COSV65423218, COSV65434312; called by muse, mutect2, varscan2
- COL4A4 | c.2780G>A p.G927E | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61632505; called by muse, mutect2, varscan2
- COL4A6 | c.690+2T>C p.X230_splice | Splice Site (SNP) | VAF 39/366 reads (11%) | catalogued as COSV57867275; called by muse, mutect2, varscan2
- COL6A3 | c.2767G>A p.A923T | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as COSV55090419, COSV99040701; called by muse, mutect2, varscan2
- COL6A3 | c.2497+2T>C p.X833_splice | Splice Site (SNP) | VAF 36/247 reads (15%) | catalogued as COSV55090438; called by muse, mutect2, varscan2
- COLEC10 | c.305A>G p.E102G | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV60521358; called by muse, mutect2, varscan2
- COLGALT1 | c.1811C>G p.A604G | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.698); catalogued as rs775620377, COSV53109302; called by muse, mutect2, varscan2
- COQ5 | c.187_189del p.E63del | In Frame Del (DEL) | VAF 21/178 reads (12%) | catalogued as rs1414769890; called by pindel, varscan2
- CORIN | c.1112A>C p.K371T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs370951437, COSV56699708; called by mutect2, varscan2
- CPEB2 | c.2767C>T p.R923* | Nonsense Mutation (SNP) | VAF 27/185 reads (15%) | catalogued as COSV52591959; called by muse, mutect2, varscan2
- CRAMP1 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.585); catalogued as rs186357261; called by muse, mutect2, varscan2
- CRNN | c.920G>A p.S307N | Missense Mutation (SNP) | VAF 16/474 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV55120933, COSV55122162; called by muse, mutect2
- CRYL1 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs369439890; called by muse, mutect2, varscan2
- CSF2RA | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.445); catalogued as rs371464087, COSV62624348; called by muse, mutect2, varscan2
- CSMD3 | c.1354A>G p.I452V (on ENST00000297405 / NM_001363185.1; = p.I348V on NM_052900.3) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1476618416, COSV52187722; called by muse, mutect2, varscan2
- CSPG4 | c.3712C>A p.P1238T | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV57895432; called by muse, mutect2
- CSTF2 | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.262); catalogued as COSV63376272; called by muse, mutect2, varscan2
- CTBP1 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1329666542, COSV52074127; called by muse, mutect2, varscan2
- CTNND2 | c.1328A>G p.D443G | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.971); catalogued as COSV58891001; called by muse, mutect2
- CTSC | c.189del p.V64* | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as rs766504984; called by mutect2, varscan2
- CYB561D1 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 48/296 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771407605, COSV60204936; called by muse, mutect2, varscan2
- CYP4A11 | c.563A>G p.H188R | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs769652273, COSV60223735; called by muse, mutect2, varscan2
- CYP4X1 | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.475); catalogued as rs965440714, COSV64150805; called by muse, mutect2, varscan2
- DAAM1 | c.2450T>C p.V817A | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62836488; called by muse, mutect2
- DAZAP1 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1461918261, COSV51833611; called by muse, mutect2, varscan2
- DBF4B | c.943C>T p.L315F | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59260846; called by muse, mutect2, varscan2
- DBH | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.22); catalogued as rs377299166; called by muse, mutect2, varscan2
- DDB1 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV57102871; called by muse, mutect2
- DENND1B | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as rs765599500, COSV52464902; called by mutect2, varscan2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as rs553532837; called by mutect2, varscan2
- DENND3 | c.2860G>A p.A954T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as COSV52802578; called by muse, mutect2, varscan2
- DIPK1B | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as rs762803885, COSV63038055; called by muse, mutect2, varscan2
- DKK1 | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as rs1307877328, COSV64760283; called by muse, mutect2
- DLAT | c.723del p.V242Wfs*5 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | catalogued as rs782029228, COSV54771743; called by mutect2, varscan2
- DLG2 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54646580; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH11 | c.3373A>G p.K1125E | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.575); catalogued as COSV60956946; called by muse, mutect2
- DNAH5 | c.10030del p.S3344Afs*11 | Frame Shift Del (DEL) | VAF 28/189 reads (15%) | catalogued as rs1307200375; called by mutect2, pindel, varscan2
- DNAJC1 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs775695831, COSV65411154; called by muse, mutect2, varscan2
- DNAJC15 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV64872281; called by muse, mutect2, varscan2
- DNAJC2 | c.77G>A p.C26Y | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.271); catalogued as COSV50790597; called by muse, mutect2, varscan2
- DNAJC21 | c.1155dup p.Q386Tfs*52 | Frame Shift Ins (INS) | VAF 28/206 reads (14%) | catalogued as rs761105777; called by mutect2, pindel, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK3 | c.5729G>A p.R1910H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.976); catalogued as rs781974113, COSV56522801; called by muse, mutect2, varscan2
- DOCK8 | c.4492G>A p.E1498K | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV66617797; called by muse, mutect2, varscan2
- DPCD | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0.361); catalogued as COSV64509326; called by muse, mutect2, varscan2
- DPPA2 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs779719606, COSV72118094; called by muse, mutect2, varscan2
- DQX1 | c.1495G>T p.A499S | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV66353233; called by muse, mutect2, varscan2
- DRD1 | c.88C>A p.L30M | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67104656; called by muse, mutect2, varscan2
- DRD3 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs149736958; called by muse, mutect2, varscan2
- DRP2 | c.2768G>A p.S923N | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV67871050; called by muse, mutect2, varscan2
- DSP | c.2719C>T p.R907C | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as rs749051278, COSV65792211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DTX1 | c.265A>G p.M89V | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1266595951, COSV57497685; called by muse, mutect2, varscan2
- E2F7 | c.2186dup p.T730Yfs*74 | Frame Shift Ins (INS) | VAF 7/41 reads (17%) | catalogued as rs36042830; called by mutect2, varscan2
- ECHDC2 | c.716T>C p.V239A (on ENST00000371522 / NM_001198961.2; = p.V208A on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64301146; called by muse, mutect2, varscan2
- EIF3G | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs530819290, COSV53452953; called by mutect2, varscan2
- ELF3 | c.907T>A p.F303I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62838404; called by muse, mutect2, varscan2
- EP300 | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54329321; called by muse, mutect2, varscan2
- EPAS1 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs370125133, COSV55386721; called by muse, mutect2, varscan2
- EPB41L5 | c.802del p.W268Gfs*4 | Frame Shift Del (DEL) | VAF 11/69 reads (16%) | catalogued as rs35675992; called by mutect2, pindel, varscan2
- EPHB3 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57806136; called by mutect2, varscan2
- ERAP1 | c.2545G>A p.A849T | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV57088132; called by muse, mutect2, varscan2
- ERBB2 | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV54063501, COSV54069910; called by muse, mutect2, varscan2
- ERCC6L2 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1211849973, COSV56629308; called by muse, mutect2, varscan2
- EVI5 | c.648del p.F216Lfs*15 | Frame Shift Del (DEL) | VAF 13/92 reads (14%) | catalogued as rs1453325274; called by mutect2, pindel, varscan2
- EVL | c.560del p.P187Hfs*41 (on ENST00000402714 / NM_001330221.2; = p.P189Hfs*41 on NM_016337.3) | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | catalogued as rs746606863; called by mutect2, varscan2
- EVPL | c.4040C>T p.A1347V | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs765962347, COSV56911335; called by muse, mutect2, varscan2
- EXO1 | c.1376T>C p.F459S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV62216204; called by muse, mutect2, varscan2
- EXO5 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV56415507; called by muse, mutect2, varscan2
- F13B | c.149G>A p.S50N | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as rs1274967585, COSV66373984; called by muse, mutect2, varscan2
- F5 | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100888837; called by muse, mutect2, varscan2
- FAM120C | c.2894T>C p.V965A | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60259540; called by muse, mutect2, varscan2
- FAM50B | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs747947650, COSV66654797; called by muse, mutect2, varscan2
- FAM83H | c.3378G>A p.M1126I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV62028491; called by muse, mutect2, varscan2
- FAM98C | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs200637370, COSV53039684; called by mutect2, varscan2
- FARP2 | c.2879_2881del p.F960del | In Frame Del (DEL) | VAF 7/65 reads (11%) | catalogued as rs775531082; called by pindel, varscan2
- FAT3 | c.9484A>G p.I3162V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV53114983; called by muse, varscan2
- FBLIM1 | c.34T>C p.S12P | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60029921; called by muse, mutect2
- FBP2 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 57/309 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100942146, COSV64694685; called by muse, mutect2, varscan2
- FBXL7 | c.932T>C p.L311P | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV61646344; called by muse, mutect2, varscan2
- FBXO32 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54890903, COSV54891143; called by muse, mutect2, varscan2
- FBXW2 | c.454T>C p.Y152H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV61597005; called by muse, mutect2, varscan2
- FCHO1 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs148410831; called by muse, mutect2, varscan2
- FCHSD2 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs755994711, COSV60810002; called by muse, mutect2, varscan2
- FCRL3 | c.552A>C p.Q184H | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV63841855; called by muse, mutect2, varscan2
- FGD3 | c.367del p.Q123Rfs*51 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | catalogued as rs777351004, COSV100490512; called by mutect2, pindel, varscan2
- FGF13 | c.678C>A p.S226R | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV59545885; called by muse, mutect2, varscan2
- FGF13 | c.68dup p.G24Wfs*28 | Frame Shift Ins (INS) | VAF 12/53 reads (23%) | catalogued as rs766041577; called by mutect2, varscan2
- FGF6 | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV57404134; called by muse, mutect2, varscan2
- FGF9 | c.41A>G p.Q14R | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.037); catalogued as COSV66644709; called by muse, mutect2, varscan2
- FHOD1 | c.2563C>T p.R855C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs772252359, COSV50761011; called by mutect2, varscan2
- FHOD3 | c.514T>C p.L172= | Splice Region (SNP) | VAF 10/42 reads (24%) | catalogued as COSV57173886; called by muse, mutect2, varscan2
- FLG2 | c.302A>G p.K101R | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV66168942; called by muse, mutect2, varscan2
- FOXRED1 | c.953C>A p.P318H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99702460; called by muse, mutect2
- FPGT | c.1050A>G p.I350M | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV63840361; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1976G>A p.G659D | Missense Mutation (SNP) | VAF 38/283 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58554937; called by muse, mutect2, varscan2
- FRAS1 | c.8367G>T p.K2789N | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV53612585; called by muse, mutect2, varscan2
- FREM1 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201834847; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FREM2 | c.884G>T p.S295I | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.522); catalogued as COSV54838747; called by muse, mutect2, varscan2
- FREM2 | c.2707G>T p.A903S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1232119699, COSV54838756; called by muse, mutect2, varscan2
- FRMD4B | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV68330170; called by muse, mutect2, varscan2
- FRMPD1 | c.1603G>A p.V535I | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs372056992; called by muse, mutect2, varscan2
- FRMPD2 | c.789-1G>A p.X263_splice | Splice Site (SNP) | VAF 14/86 reads (16%) | catalogued as COSV59718286; called by muse, mutect2, varscan2
- FTO | c.289A>G p.I97V | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.112); catalogued as rs368658799; called by muse, mutect2, varscan2
- G3BP1 | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 45/250 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV62366193; called by muse, mutect2, varscan2
- GABRA6 | c.412A>G p.I138V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV50881974, COSV50896316; called by muse, mutect2, varscan2
- GABRG1 | c.792dup p.D265* | Frame Shift Ins (INS) | VAF 16/94 reads (17%) | catalogued as rs772301203; called by mutect2, varscan2
- GALNT11 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV57426094; called by muse, mutect2, varscan2
- GBX1 | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 90/500 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.797); catalogued as COSV52547637; called by muse, mutect2, varscan2
- GCHFR | c.206G>T p.S69I | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV53066943; called by muse, mutect2, varscan2
- GFOD1 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.389); catalogued as COSV64954736; called by muse, mutect2, varscan2
- GFRA2 | c.521G>A p.C174Y | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV60779152; called by muse, mutect2
- GIGYF2 | c.2416C>T p.R806* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV65249671; called by mutect2, varscan2
- GJA4 | c.115C>A p.L39M | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV100654609; called by muse, mutect2
- GNB4 | c.692C>G p.A231G | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.868); catalogued as COSV51709655; called by muse, mutect2, varscan2
- GNPDA1 | c.353G>A p.C118Y | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60942484; called by muse, mutect2, varscan2
- GPATCH8 | c.2238_2240del p.R749del | In Frame Del (DEL) | VAF 14/76 reads (18%) | catalogued as rs778513845; called by pindel, varscan2
- GPR153 | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV64938562; called by muse, mutect2, varscan2
- GPR20 | c.859A>G p.S287G | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV66684490; called by muse, mutect2, varscan2
- GPR31 | c.461A>G p.E154G | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.065); catalogued as COSV64761482; called by muse, mutect2, varscan2
- GPR6 | c.232C>T p.L78F | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV51571994; called by muse, mutect2, varscan2
- GPR68 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs146326486; called by mutect2, varscan2
- GPRASP2 | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV59991388; called by muse, mutect2, varscan2
- GPRC6A | c.419T>G p.V140G | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV59953186; called by muse, mutect2
- GPRIN3 | c.1124G>A p.S375N | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV60885025; called by muse, mutect2
- GRB7 | c.1241T>C p.M414T | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV58448118; called by muse, mutect2, varscan2
- GRIA2 | c.2224A>G p.M742V | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52412065; called by muse, mutect2, varscan2
- GRIK2 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.785); catalogued as COSV59738251; called by mutect2, varscan2
- GRM2 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as rs372298669; called by muse, mutect2, varscan2
- GRM2 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764159304, COSV56585061; called by muse, mutect2, varscan2
- GRM5 | c.715G>T p.G239W | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100549827; called by muse, mutect2, varscan2
- GRN | c.1721G>A p.R574H | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.08); catalogued as rs756117423, COSV50006150; called by muse, mutect2, varscan2
- GSDMA | c.434A>C p.D145A | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV56976778; called by muse, mutect2, varscan2
- GTPBP3 | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1025794329, COSV50178639; called by muse, mutect2, varscan2
- GUF1 | c.507+1G>A p.X169_splice | Splice Site (SNP) | VAF 28/251 reads (11%) | catalogued as COSV55782790; called by muse, mutect2, varscan2
- HCN1 | c.1446T>G p.N482K | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV57512456; called by muse, mutect2, varscan2
- HDLBP | c.3412G>A p.V1138I | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs753509915, COSV60495991; called by muse, mutect2, varscan2
- HELT | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV58819945; called by muse, varscan2
- HIPK4 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs201121603, COSV52521230; called by muse, mutect2, varscan2
- HIVEP3 | c.5522C>A p.A1841D | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs760265220, COSV56015856; called by muse, mutect2, varscan2
- HLA-A | c.212C>A p.P71Q | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65140769; called by muse, mutect2, varscan2
- HLA-B | c.620-2A>C p.X207_splice | Splice Site (SNP) | VAF 45/218 reads (21%) | catalogued as COSV69521368; called by muse, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 16/90 reads (18%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPL | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55492738; called by muse, mutect2
- HOGA1 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs367707918; called by muse, mutect2, varscan2
- HOOK3 | c.1378A>G p.T460A | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV56882627; called by muse, mutect2, varscan2
- HOXA1 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58029350; called by muse, mutect2, varscan2
- HOXD1 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs1425541814, COSV58923564; called by muse, mutect2
- HPN | c.1053C>T p.G351= | Splice Region (SNP) | VAF 26/136 reads (19%) | catalogued as rs372630062; called by muse, mutect2, varscan2
- HPS1 | c.1162A>T p.S388C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV57267987; called by muse, mutect2, varscan2
- HRNR | c.5650T>C p.Y1884H | Missense Mutation (SNP) | VAF 103/2426 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV100913845, COSV64258230; called by muse, mutect2
- HS3ST2 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as COSV54462472; called by mutect2, varscan2
- HTR3A | c.759C>A p.S253R | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55469578; called by muse, mutect2
- HTR3C | c.1245G>T p.W415C | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59175450; called by muse, mutect2
- HTRA1 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.042); catalogued as rs754158219, COSV64564263; called by muse, mutect2, varscan2
- HUWE1 | c.10274G>A p.S3425N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV53346364; called by mutect2, varscan2
- IBTK | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.324); catalogued as COSV60393075; called by muse, mutect2, varscan2
- IFNK | c.261C>A p.F87L | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as rs992332565, COSV51780773; called by muse, mutect2, varscan2
- IGBP1 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV60556424; called by muse, mutect2, varscan2
- IGHA1 | c.791G>A p.W264* | Nonsense Mutation (SNP) | VAF 15/97 reads (15%) | catalogued as rs1187742992; called by muse, mutect2, varscan2
- IGHA1 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1407946868; called by muse, mutect2
- IGSF9 | c.154del p.L52Cfs*79 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs753928344; called by mutect2, pindel, varscan2
- IL15RA | c.760A>C p.S254R | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV66092713; called by muse, mutect2, varscan2
- IMPG2 | c.889T>C p.S297P | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV51978680; called by muse, mutect2, varscan2
- INCENP | c.809C>A p.P270Q | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV53916100; called by muse, mutect2, varscan2
- INHBB | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs554007199, COSV54677973; called by muse, mutect2, varscan2
- INTS1 | c.6255G>A p.S2085= | Splice Region (SNP) | VAF 16/97 reads (16%) | catalogued as rs768393731, COSV67177576; called by muse, mutect2, varscan2
- INTS9 | c.1810A>G p.S604G | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs1444889860, COSV101273779; called by muse, mutect2, varscan2
- IPO7 | c.1720A>G p.T574A | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs780713401, COSV63352648; called by muse, mutect2, varscan2
- IRF1 | c.965C>A p.P322H | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV55377266; called by muse, varscan2
- ITGA7 | c.3030C>A p.S1010R (on ENST00000555728; = p.S966R on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV57695588; called by muse, mutect2, varscan2
- ITGB2 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs752291593, COSV56610349, COSV56610568; called by muse, mutect2, varscan2
- ITGB6 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760839315, COSV51792282; called by muse, mutect2, varscan2
- ITIH6 | c.674T>A p.I225N | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV54489429; called by muse, mutect2, varscan2
- ITPRIP | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV53391659; called by muse, mutect2
- JUP | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782061304, COSV60278106; ClinVar: uncertain significance; called by muse, mutect2
- KAZN | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1263541111, COSV63208038; called by muse, mutect2, varscan2
- KCNA6 | c.767del p.G256Afs*41 | Frame Shift Del (DEL) | VAF 26/172 reads (15%) | catalogued as COSV54975156, COSV99768463; called by mutect2, pindel, varscan2
- KCNA6 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99768260; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 24/155 reads (15%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNJ3 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54535098; called by muse, mutect2, varscan2
- KCTD8 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV63589454; called by muse, mutect2, varscan2
- KDM3A | c.3144G>A p.W1048* | Nonsense Mutation (SNP) | VAF 5/54 reads (9%) | catalogued as COSV57221347; called by muse, mutect2
- KDM5B | c.3700C>T p.P1234S | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0.019); catalogued as COSV52507991; called by muse, mutect2, varscan2
- KIAA1109 | c.14227C>T p.R4743C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs767116983, COSV52662892; called by muse, mutect2, varscan2
- KIF13B | c.1882C>T p.R628C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs769742692, COSV73054427; called by mutect2, varscan2
- KIF15 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs147576633; called by muse, mutect2, varscan2
- KIF17 | c.2470G>A p.A824T | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56118389, COSV56120003; called by muse, mutect2, varscan2
- KIF26B | c.3884G>A p.C1295Y | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.174); catalogued as COSV63642007; called by muse, mutect2
- KIN | c.505del p.T169Lfs*9 | Frame Shift Del (DEL) | VAF 55/288 reads (19%) | catalogued as rs769387138, COSV65430366; called by mutect2, pindel, varscan2
- KLC1 | c.885+2T>G p.X295_splice | Splice Site (SNP) | VAF 15/97 reads (15%) | catalogued as COSV55808095; called by muse, mutect2, varscan2
- KLC2 | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1463787230, COSV57582676; called by muse, mutect2, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 28/156 reads (18%) | catalogued as COSV54711577; called by mutect2, pindel, varscan2
- KMT2A | c.7108C>A p.L2370I | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.06); catalogued as rs782655113, COSV63286038; called by muse, mutect2, varscan2
- KMT2B | c.1603C>T p.R535C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1333513923, COSV52890659; called by muse, mutect2, varscan2
- KPNA2 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 59/480 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.281); catalogued as COSV57857598; called by muse, mutect2, varscan2
- KPNA5 | c.8C>A p.A3D | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV62652562; called by muse, mutect2, varscan2
- KRT24 | c.453G>T p.L151F | Missense Mutation (SNP) | VAF 16/360 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52880322; called by muse, mutect2
- KRT73 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV59839362; called by muse, mutect2, varscan2
- KRT75 | c.200del p.G67Vfs*65 | Frame Shift Del (DEL) | VAF 14/97 reads (14%) | catalogued as rs753856803; called by mutect2, pindel, varscan2
- KRTAP10-7 | c.135del p.C46Afs*8 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | catalogued as rs781883869, COSV100170027; called by mutect2, varscan2
- KYNU | c.729+2T>C p.X243_splice | Splice Site (SNP) | VAF 24/129 reads (19%) | catalogued as rs1398715804, COSV51583966; called by muse, mutect2, varscan2
- LAMA1 | c.5653C>A p.L1885M | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV67537551; called by muse, mutect2, varscan2
- LAMA1 | c.3169G>A p.D1057N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.062); catalogued as rs141907708; called by muse, mutect2, varscan2
- LAMB4 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV52720067, COSV99223620; called by muse, mutect2
- LCN6 | c.220T>G p.S74A | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.25); catalogued as COSV57910549; called by muse, mutect2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | catalogued as COSV65473126, COSV65473260; called by mutect2, varscan2
- LENG1 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs974716521, COSV55363531; called by muse, mutect2, varscan2
- LEXM | c.515A>C p.K172T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as COSV64022778; called by muse, mutect2, varscan2
- LGALS2 | c.133C>T p.H45Y | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50756548, COSV50757990; called by muse, mutect2, varscan2
- LIG3 | c.469dup p.I157Nfs*16 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | catalogued as rs745989900; called by mutect2, varscan2
- LILRB2 | c.1546G>A p.G516S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.913); catalogued as COSV100078923; called by muse, mutect2, varscan2
- LIMK1 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.251); catalogued as rs1407930830, COSV60281280; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 17/108 reads (16%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LONRF1 | c.1215G>T p.E405D | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV68036900; called by muse, mutect2, varscan2
- LRCH3 | c.1853T>G p.V618G | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV58392180; called by muse, mutect2, varscan2
- LRFN2 | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs774490346, COSV57827749; called by muse, mutect2, varscan2
- LRRC37A3 | c.4282G>A p.A1428T | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as rs752877809, COSV58536385; called by muse, mutect2, varscan2
- LRRCC1 | c.1506del p.K502Nfs*2 | Frame Shift Del (DEL) | VAF 36/227 reads (16%) | catalogued as rs1251290668, COSV64483107; called by mutect2, pindel, varscan2
- LRRIQ1 | c.680A>G p.Q227R | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV67813096; called by muse, mutect2, varscan2
- LRRK2 | c.490T>G p.F164V | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.056); catalogued as COSV54154083; called by muse, mutect2
- LRRK2 | c.4915del p.R1639Gfs*15 | Frame Shift Del (DEL) | VAF 26/138 reads (19%) | catalogued as rs756089224; called by mutect2, varscan2
- LRRN2 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); catalogued as rs139753603; called by muse, mutect2, varscan2
- LRRTM4 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs1289836030, COSV69138812, COSV69141526; called by muse, mutect2, varscan2
- LSM14A | c.1243C>A p.L415I | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV70885139; called by muse, mutect2, varscan2
- LY6D | c.113G>A p.C38Y | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56661226; called by muse, mutect2, varscan2
- LZTS1 | c.1607A>C p.K536T | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56116915; called by muse, mutect2, varscan2
- LZTS1 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.158); catalogued as COSV56116923; called by muse, mutect2, varscan2
- MACF1 | c.11741G>A p.S3914N (on ENST00000372915; = p.S1847N on NM_012090.5) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as COSV57122312; called by muse, mutect2, varscan2
- MACF1 | c.20458C>T p.R6820* (on ENST00000372915; = p.R4865* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 50/216 reads (23%) | catalogued as COSV57122335; called by muse, mutect2, varscan2
- MAG | c.1381G>A p.V461M | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV62699057; called by muse, mutect2, varscan2
- MAGEA3 | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64756217; called by muse, mutect2, varscan2
- MAGEC3 | c.150C>A p.D50E | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as COSV53580710; called by muse, mutect2, varscan2
- MAP1A | c.6193del p.R2065Vfs*5 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | catalogued as COSV55811343; called by mutect2, pindel
- MAP3K1 | c.1567G>A p.V523I | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1483289809, COSV68123901; called by muse, mutect2, varscan2
- MAP3K10 | c.785G>A p.S262N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53422512; called by muse, mutect2, varscan2
- MAP7 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.556); catalogued as rs368985967; called by muse, mutect2, varscan2
- MAP7D1 | c.245dup p.Q83Afs*8 | Frame Shift Ins (INS) | VAF 14/103 reads (14%) | catalogued as rs765962881; called by mutect2, varscan2
- MAPK7 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55190548; called by muse, mutect2, varscan2
- MARCHF7 | c.886del p.S296Hfs*9 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | catalogued as rs1383130845; called by mutect2, varscan2
- MARK4 | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs753337213, COSV53464195; called by muse, mutect2, varscan2
- MARVELD2 | c.1550del p.K517Rfs*16 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs753107989; called by mutect2, varscan2
- MASTL | c.755C>A p.P252H | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV60910956; called by muse, mutect2, varscan2
- MATK | c.1067G>A p.R356H (on ENST00000310132 / NM_139355.3; = p.R357H on NM_002378.4) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59554696; called by muse, mutect2, varscan2
- MBNL1 | c.931G>A p.A311T (on ENST00000282486 / NM_207293.2; = p.A293T on NM_021038.5 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as rs748628776, COSV56828659; called by muse, mutect2, varscan2
- MCF2L | c.1274C>T p.A425V (on ENST00000375608; = p.A393V on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201603170; called by muse, mutect2, varscan2
- MCF2L | c.3130G>A p.A1044T (on ENST00000375608; = p.A1012T on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.349); catalogued as rs749848889, COSV56177773; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 20/100 reads (20%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCM2 | c.1744G>T p.G582* | Nonsense Mutation (SNP) | VAF 39/188 reads (21%) | catalogued as COSV54033986; called by muse, mutect2, varscan2
- MCM3 | c.674G>A p.R225H (on ENST00000229854 / NM_001366374.2; = p.R215H on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377411679; called by muse, mutect2, varscan2
- MDM4 | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV65795681; called by muse, mutect2, varscan2
- MED15 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated, low confidence (0.73); PolyPhen probably damaging (0.989); catalogued as COSV53029435; called by muse, mutect2, varscan2
- MEGF8 | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs769196067, COSV52079924; called by muse, mutect2, varscan2
- MEPCE | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); catalogued as COSV52769226; called by muse, mutect2, varscan2
- MFN2 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52422556; called by muse, mutect2, varscan2
- MGA | c.5392A>G p.M1798V (on ENST00000219905 / NM_001164273.1; = p.M1589V on NM_001080541.2) | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as rs1226227637, COSV54954293; called by muse, varscan2
- MGAT2 | c.891T>A p.S297R | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.07); catalogued as COSV53566049; called by muse, varscan2
- MGST2 | c.309del p.K103Nfs*8 | Frame Shift Del (DEL) | VAF 18/110 reads (16%) | catalogued as COSV55498546; called by pindel, varscan2
- MIDN | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs760302974, COSV56295118; called by muse, mutect2, varscan2
- MIOS | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV60768543, COSV60771125; called by muse, mutect2, varscan2
- MIPOL1 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV59384593; called by muse, mutect2, varscan2
- MIS18BP1 | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs757638957, COSV60370974; called by muse, varscan2
- MMP16 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs780162250, COSV54149241; called by muse, varscan2
- MOCOS | c.1418C>T p.S473L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201324027, COSV54343587; called by muse, mutect2, varscan2
- MON2 | c.1525G>T p.E509* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | catalogued as COSV54807622; called by muse, mutect2, varscan2
- MORC2 | c.1813-3del | Splice Region (DEL) | VAF 9/30 reads (30%) | catalogued as rs777649506, COSV53202254; called by mutect2, varscan2
- MORC4 | c.231G>T p.E77D | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.26); catalogued as COSV55242481; called by muse, mutect2, varscan2
- MPHOSPH10 | c.711del p.F237Lfs*28 | Frame Shift Del (DEL) | VAF 28/138 reads (20%) | catalogued as rs1179926988; called by mutect2, pindel, varscan2
- MRGPRX1 | c.560del p.L187Yfs*13 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | catalogued as rs1390190298; called by mutect2, varscan2
- MRGPRX1 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.365); catalogued as rs1305417663, COSV57107474; called by muse, mutect2, varscan2
- MRO | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV56496111; called by muse, mutect2, varscan2
- MROH2B | c.3931A>G p.S1311G | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.02); catalogued as COSV68184534; called by muse, mutect2, varscan2
- MROH2B | c.2608G>T p.G870* | Nonsense Mutation (SNP) | VAF 22/114 reads (19%) | catalogued as COSV68184539; called by muse, mutect2, varscan2
- MRPL24 | c.52del p.H18Ifs*6 | Frame Shift Del (DEL) | VAF 19/117 reads (16%) | catalogued as rs760797871; called by mutect2, pindel, varscan2
- MRPL28 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs749118796, COSV51739424; called by muse, mutect2, varscan2
- MS4A12 | c.437C>G p.S146C | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as COSV50014311, COSV99188741; called by muse, mutect2, varscan2
- MSH5 | c.737G>A p.S246N | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.047); catalogued as rs1480408717, COSV65209761; called by muse, mutect2, varscan2
- MTCL1 | c.1138C>T p.R380W (on ENST00000306329 / NM_001378206.1; = p.R20W on NM_015210.4) | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60406272; called by muse, mutect2, varscan2
- MTIF2 | c.153G>A p.W51* | Nonsense Mutation (SNP) | VAF 11/97 reads (11%) | catalogued as COSV55051685; called by muse, mutect2, varscan2
- MTMR8 | c.25-1G>C p.X9_splice | Splice Site (SNP) | VAF 12/81 reads (15%) | catalogued as COSV66392434, COSV66393978; called by muse, mutect2, varscan2
- MUC16 | c.8807del p.N2936Tfs*6 | Frame Shift Del (DEL) | VAF 18/142 reads (13%) | catalogued as COSV101198428, COSV104431809; called by mutect2, pindel, varscan2
- MUC17 | c.4190C>T p.P1397L | Missense Mutation (SNP) | VAF 86/637 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as rs141608296, COSV60280453; called by muse, mutect2, varscan2
- MUC4 | c.2591C>T p.A864V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.494); catalogued as rs372862585; called by muse, mutect2, varscan2
- MXRA5 | c.8107G>A p.V2703M | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54235978; called by muse, mutect2, varscan2
- MXRA5 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs148104868, COSV54231620; called by muse, mutect2, varscan2
- MYADM | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs757660078, COSV61238598; called by muse, mutect2, varscan2
- MYH15 | c.40del p.W14Gfs*5 | Frame Shift Del (DEL) | VAF 12/107 reads (11%) | catalogued as rs752868848; called by mutect2, pindel, varscan2
- MYH7 | c.1435A>G p.N479D | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs1555338261, COSV62519551; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO10 | c.5188A>G p.I1730V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.591); catalogued as COSV57022036; called by muse, mutect2, varscan2
- MYO16 | c.3002C>T p.T1001I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as rs901587939, COSV62750608; called by muse, mutect2, varscan2
- MYO18B | c.7195C>A p.L2399I | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV100123634, COSV59135136; called by muse, mutect2, varscan2
- MYO5C | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs943150513, COSV55906769; called by muse, mutect2
- NAT2 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.1); catalogued as rs761144507, COSV54062090; called by muse, mutect2, varscan2
- NAV1 | c.481del p.L161Wfs*33 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | catalogued as rs1346393455; called by mutect2, pindel, varscan2
- NAV1 | c.1449del p.K483Nfs*9 | Frame Shift Del (DEL) | VAF 27/159 reads (17%) | catalogued as COSV55224089; called by mutect2, pindel, varscan2
- NBEA | c.5918C>T p.A1973V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV59786436; called by muse, mutect2, varscan2
- NBEA | c.7419del p.K2473Nfs*13 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as rs754479937; called by pindel, varscan2
- NCALD | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV55272655; called by muse, mutect2, varscan2
- NCAPD2 | c.3383A>G p.K1128R | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV59699534; called by muse, mutect2, varscan2
- NDN | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.486); catalogued as COSV59359546; called by mutect2, varscan2
- NDST1 | c.1259G>A p.G420D | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.862); catalogued as rs1245456252, COSV55787463; called by muse, mutect2
- NDUFB2 | c.199T>C p.F67L | Missense Mutation (SNP) | VAF 50/289 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52595422, COSV52596057; called by muse, mutect2, varscan2
- NEB | c.17662C>A p.L5888I | Missense Mutation (SNP) | VAF 75/472 reads (16%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.992); catalogued as COSV51419173; called by muse, mutect2, varscan2
- NECTIN2 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs1188434646, COSV52977543; called by muse, mutect2, varscan2
- NELL2 | c.1523G>A p.C508Y | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61575366; called by muse, mutect2, varscan2
- NEU3 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV53636698; called by muse, mutect2, varscan2
- NEURL2 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV51942298, COSV99510128; called by muse, mutect2, varscan2
- NFIL3 | c.233A>G p.E78G | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52682870, COSV52683727; called by muse, mutect2
- NIPBL | c.6427T>A p.S2143T | Missense Mutation (SNP) | VAF 57/323 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV56951818; called by muse, mutect2, varscan2
- NKAPL | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV59198000; called by muse, mutect2, varscan2
- NLGN2 | c.1621T>G p.F541V | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57210284; called by muse, mutect2
- NLRP12 | c.3151C>T p.R1051* | Nonsense Mutation (SNP) | VAF 14/95 reads (15%) | catalogued as rs199475871, COSV60747930; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NMRK2 | c.502G>T p.V168F | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV51455474; called by muse, varscan2
- NPAT | c.2786-3del | Splice Region (DEL) | VAF 11/75 reads (15%) | catalogued as rs35747263; called by mutect2, pindel, varscan2
- NPHS2 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs201355305, COSV62634950; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPNT | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.996); catalogued as COSV59753950; called by muse, mutect2, varscan2
- NR1D1 | c.754C>A p.P252T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV52843103; called by muse, mutect2
- NR1I2 | c.1042C>A p.L348I | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.958); catalogued as COSV61978435; called by muse, mutect2, varscan2
- NR5A1 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as rs944569341, COSV65294925; called by muse, mutect2, varscan2
- NRG3 | c.1786A>G p.S596G (on ENST00000404547 / NM_001370084.1; = p.S572G on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.115); catalogued as COSV64563170; called by muse, mutect2, varscan2
- NRK | c.3344C>T p.A1115V | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV54597148; called by muse, mutect2, varscan2
- NSMCE2 | c.109G>T p.G37C | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54898367; called by muse, varscan2
- NSRP1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55933972; called by muse, mutect2, varscan2
- NTNG2 | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1323792184, COSV62366824; called by muse, mutect2, varscan2
- NUDCD1 | c.453A>T p.K151N | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs996136481, COSV53457168, COSV53460805; called by muse, mutect2, varscan2
- NWD1 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.342); catalogued as rs746626131, COSV60342957; called by muse, mutect2, varscan2
- NYAP2 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 45/243 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758742709, COSV56005642; called by muse, mutect2, varscan2
- OAS2 | c.1277del p.N426Tfs*14 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | catalogued as rs781171419; called by mutect2, varscan2
- OBSCN | c.20977del p.A6993Pfs*79 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | catalogued as rs762005098; called by mutect2, pindel, varscan2
- OOEP | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.214); catalogued as rs1393489413, COSV64859261; called by muse, mutect2
- OPHN1 | c.778T>C p.C260R | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.605); catalogued as COSV62782539; called by muse, mutect2, varscan2
- OR10A4 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.461); catalogued as COSV65842056; called by muse, mutect2, varscan2
- OR10AG1 | c.848T>C p.L283P | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs777667275, COSV56633084; called by muse, mutect2, varscan2
- OR13J1 | c.699G>T p.R233S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs920454679, COSV65069778; called by muse, mutect2, varscan2
- OR2L8 | c.499T>C p.Y167H | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61726909; called by muse, mutect2, varscan2
- OR2T33 | c.433T>C p.S145P | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.154); catalogued as COSV58813694; called by muse, mutect2
- OR52E6 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV100259039; called by muse, mutect2, varscan2
- OR5V1 | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1480303301, COSV65828087; called by muse, mutect2, varscan2
- OR6C4 | c.164C>G p.T55S | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV67793004, COSV67793342; called by muse, mutect2, varscan2
- OR6M1 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs778923568, COSV58432789; called by muse, mutect2, varscan2
- OR8B8 | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.068); catalogued as COSV60144649; called by muse, mutect2, varscan2
- ORC6 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV54478940; called by muse, mutect2
- OSBP2 | c.2678C>T p.A893V | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.101); catalogued as COSV60242416, COSV60243301; called by muse, mutect2, varscan2
- OSCP1 | c.101A>C p.K34T | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1202099444, COSV52486271; called by muse, mutect2, varscan2
- P2RY14 | c.836T>C p.F279S | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.143); catalogued as rs1422097265, COSV56379886; called by muse, mutect2, varscan2
- PABPC1 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as COSV59401788; called by muse, mutect2
- PACSIN1 | c.611A>G p.K204R | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as COSV55060218; called by muse, mutect2, varscan2
- PARP4 | c.4249C>T p.P1417S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV67961449; called by muse, mutect2, varscan2
- PARP9 | c.625T>C p.C209R | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV100830870; called by muse, mutect2, varscan2
- PASK | c.962G>A p.S321N | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.15); catalogued as COSV52153143, COSV99298585; called by muse, mutect2, varscan2
- PCDH19 | c.752C>A p.S251* | Nonsense Mutation (SNP) | VAF 29/224 reads (13%) | catalogued as COSV55263509, COSV99720811; called by muse, mutect2, varscan2
- PCDHA6 | c.1963G>A p.G655S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs782721177, COSV65344323; called by muse, mutect2, varscan2
- PCDHB12 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV53396857; called by muse, mutect2, varscan2
- PCDHGA10 | c.1873del p.E625Sfs*23 | Frame Shift Del (DEL) | VAF 22/152 reads (14%) | catalogued as rs773120396; called by mutect2, pindel, varscan2
- PCDHGA6 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.73); catalogued as rs1194415432, COSV53906621; called by muse, mutect2
- PCDHGB1 | c.1856C>T p.T619M | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54005003; called by muse, mutect2, varscan2
- PCM1 | c.2237T>C p.L746P | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61516408; called by muse, mutect2, varscan2
- PCNT | c.6143G>A p.G2048D | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs375301097; called by muse, mutect2
- PCNX1 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.978); catalogued as rs1037443498, COSV53095100; called by muse, mutect2, varscan2
- PCNX2 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs1427043947, COSV50804514; called by muse, mutect2, varscan2
- PCOLCE | c.894del p.K299Sfs*41 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | catalogued as rs755349242; called by mutect2, pindel, varscan2
- PCYT1A | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375663930; called by muse, mutect2, varscan2
- PDCD4 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as COSV54523032; called by muse, mutect2, varscan2
- PDE4B | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761147896, COSV58477767; called by muse, mutect2, varscan2
- PDE7A | c.839T>C p.V280A (on ENST00000401827 / NM_001242318.3; = p.V254A on NM_002603.4) | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65153179; called by muse, mutect2, varscan2
- PDXP | c.509A>C p.E170A | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1189118493, COSV53216639; called by muse, mutect2, varscan2
- PDZD2 | c.662T>C p.V221A | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV56858904; called by muse, mutect2, varscan2
- PDZD4 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs782639746, COSV51246894; called by muse, mutect2, varscan2
- PFKP | c.793del p.R265Gfs*2 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | catalogued as rs1161592176; called by mutect2, varscan2
- PGAM5 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58202150; called by muse, mutect2, varscan2
- PGR | c.2733A>C p.E911D | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs865856373, COSV54798625, COSV99678444; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs769717544; called by mutect2, varscan2
- PHYKPL | c.81dup p.P28Sfs*6 | Frame Shift Ins (INS) | VAF 20/166 reads (12%) | catalogued as rs530484554; called by mutect2, pindel, varscan2
- PIEZO2 | c.7685G>A p.R2562Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs1333324116, COSV53286204; called by muse, mutect2
- PIP5K1C | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs377291771, COSV58950241; called by muse, mutect2, varscan2
- PLCD1 | c.584C>A p.S195Y | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.017); catalogued as COSV52184844; called by muse, mutect2, varscan2
- PLEKHG1 | c.32G>A p.S11N | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62047673; called by muse, mutect2, varscan2
- PLEKHG6 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as rs760587478, COSV99164032; called by muse, mutect2, varscan2
- PLRG1 | c.1220A>T p.Q407L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV57423601; called by muse, mutect2, varscan2
- PLXDC1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1345241544, COSV59551242; called by muse, mutect2, varscan2
- PLXNA4 | c.1376G>A p.R459Q | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.818); catalogued as COSV58128366; called by muse, mutect2, varscan2
- PMEPA1 | c.264A>G p.S88= | Splice Region (SNP) | VAF 9/33 reads (27%) | catalogued as COSV55693742; called by muse, mutect2, varscan2
- POLR3A | c.3701C>T p.A1234V | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.119); catalogued as COSV64931079; called by muse, mutect2, varscan2
- POLR3K | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs144406744; called by muse, mutect2, varscan2
- POMGNT1 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 16/88 reads (18%) | PolyPhen probably damaging (0.977); catalogued as rs766157232, COSV64339934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POMT2 | c.1976G>A p.R659Q | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770606360, COSV55071334; called by muse, mutect2, varscan2
- POP1 | c.2305G>A p.A769T | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.036); catalogued as COSV62892855; called by muse, mutect2, varscan2
- POTEE | c.2237del p.G746Afs*20 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | catalogued as rs1229339641; called by mutect2, varscan2
- PPARD | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs201653737, COSV61099768; called by muse, mutect2, varscan2
- PPARG | c.1190A>G p.E397G (on ENST00000287820 / NM_015869.5; = p.E367G on NM_005037.7) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV55142616; called by muse, mutect2, varscan2
- PPIL1 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV63836884; called by muse, mutect2, varscan2
- PPL | c.1362del p.T455Qfs*37 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | catalogued as rs753902804; called by mutect2, pindel, varscan2
- PPP1R11 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV54993393; called by muse, mutect2, varscan2
- PPP1R14A | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV56646476; called by muse, mutect2, varscan2
- PPP1R16B | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as rs774196620, COSV55378047; called by muse, mutect2, varscan2
- PPP1R3A | c.511G>C p.D171H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52880850, COSV52883284; called by muse, mutect2, varscan2
- PPP1R3B | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs771689160, COSV60099558; called by muse, mutect2, varscan2
- PRDM15 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.034); catalogued as COSV54152990; called by muse, mutect2, varscan2
- PREX2 | c.1693del p.S565Rfs*10 | Frame Shift Del (DEL) | VAF 17/102 reads (17%) | catalogued as rs764112302; called by mutect2, varscan2
- PRKCB | c.149G>T p.C50F | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57804046; called by muse, mutect2, varscan2
- PRKCG | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV54728119; called by muse, mutect2, varscan2
- PRORP | c.714del p.V239Lfs*2 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | catalogued as rs780434139; called by mutect2, pindel, varscan2
- PRR5L | c.443A>G p.Q148R | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV61121513; called by muse, mutect2, varscan2
- PRRC2A | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1175890119, COSV101051158, COSV65686647; called by muse, mutect2, varscan2
- PRSS36 | c.2038del p.L680Wfs*6 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs771809480; called by mutect2, pindel, varscan2
- PSD3 | c.578del p.N193Ifs*11 | Frame Shift Del (DEL) | VAF 35/160 reads (22%) | catalogued as rs776786486, COSV58974718; called by mutect2, varscan2
- PSMC2 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1239171805, COSV53007529; called by muse, mutect2, varscan2
- PTBP1 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs775749591, COSV62459231; called by muse, mutect2, varscan2
- PTBP1 | c.1252C>T p.R418C (on ENST00000349038 / NM_031991.4; = p.R444C on NM_002819.5) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as rs766285321, COSV62460065; called by muse, mutect2
- PTPN5 | c.1409dup p.L471Tfs*304 | Frame Shift Ins (INS) | VAF 13/87 reads (15%) | catalogued as rs761650832; called by mutect2, varscan2
- PTPRC | c.2691A>C p.Q897H | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61405854, COSV61412086, COSV61419400; called by muse, mutect2, varscan2
- PTPRT | c.2995C>T p.R999* | Nonsense Mutation (SNP) | VAF 14/79 reads (18%) | catalogued as rs763964405, COSV62002420; called by muse, mutect2, varscan2
- PTPRT | c.2314A>C p.R772= | Splice Region (SNP) | VAF 19/110 reads (17%) | catalogued as COSV61982822; called by muse, mutect2, varscan2
- PTPRT | c.1670A>G p.Y557C | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61982828; called by muse, mutect2, varscan2
- PTPRZ1 | c.5621A>C p.N1874T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66437153; called by muse, mutect2, varscan2
- PURA | c.638A>C p.E213A | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV58762244; called by muse, mutect2, varscan2
- PWWP3A | c.1202T>C p.V401A (on ENST00000627377; = p.V400A on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV60902361; called by muse, mutect2, varscan2
- PWWP3B | c.1649A>G p.D550G | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV100531689, COSV61799881; called by muse, mutect2, varscan2
- PXDNL | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as rs1289780089, COSV62487760; called by muse, mutect2
- PYCR1 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs772766530, COSV61696693; called by muse, mutect2
- QDPR | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs1345547809, COSV55550087; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs371085767; called by muse, mutect2, varscan2
- RAB3GAP1 | c.153T>C p.G51= | Splice Region (SNP) | VAF 21/114 reads (18%) | catalogued as rs1388728601, COSV51480060; called by muse, mutect2, varscan2
- RAI1 | c.4294C>A p.P1432T | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.261); catalogued as COSV55393322; called by muse, mutect2
- RALY | c.717C>A p.S239R (on ENST00000246194 / NM_016732.3; = p.S223R on NM_007367.4) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.105); catalogued as COSV55781310, COSV99865818; called by muse, mutect2
- RAPH1 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.283); catalogued as COSV57353383; called by muse, mutect2
- RASA1 | c.2513del p.N838Mfs*4 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | catalogued as rs1561325048; called by mutect2, pindel, varscan2
- RAVER1 | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs201609635; called by muse, mutect2, varscan2
- RBM23 | c.709A>G p.I237V (on ENST00000359890 / NM_001077351.2; = p.I221V on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs753063318, COSV57127823; called by muse, mutect2, varscan2
- RBM4 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.454); catalogued as rs768616980, COSV59518866; called by muse, mutect2, varscan2
- RERG | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 27/147 reads (18%) | catalogued as rs767703721, COSV57001358; called by muse, mutect2, varscan2
- RETSAT | c.44C>A p.A15D | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.154); catalogued as COSV55526263; called by muse, mutect2, varscan2
- RFC3 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV66296630; called by muse, mutect2, varscan2
- RFX6 | c.2363G>A p.C788Y | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV60585169; called by muse, mutect2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RGS14 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV68771278; called by muse, mutect2, varscan2
- RGS22 | c.833T>G p.V278G | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV62662049; called by muse, mutect2, varscan2
- RHBDL2 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV56708210; called by mutect2, varscan2
- RNF17 | c.2244C>T p.I748= | Splice Region (SNP) | VAF 14/88 reads (16%) | catalogued as rs756925498, COSV55034577; called by muse, mutect2, varscan2
- RNH1 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs768887568, COSV57278241; called by muse, mutect2, varscan2
- RORB | c.768A>C p.E256D (on ENST00000396204 / NM_001365023.1; = p.E245D on NM_006914.4) | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV65336067; called by muse, mutect2, varscan2
- RP1 | c.3736G>A p.A1246T | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV55117496; called by muse, mutect2, varscan2
- RPGRIP1 | c.3605C>A p.P1202H | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV52850394; called by muse, mutect2, varscan2
- RPL13A | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.179); catalogued as rs1180068657, COSV52619214; called by muse, mutect2
- RPL22 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs751690139, COSV99329550; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL9 | c.373A>G p.R125G | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1206871094, COSV54695836; called by muse, mutect2
- RPRM | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV57988833, COSV57989045; called by muse, mutect2, varscan2
- RPS14 | c.228G>T p.L76F | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV56316255; called by muse, mutect2, varscan2
- RPS6KB1 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56676886, COSV99847425; called by muse, mutect2, varscan2
- RREB1 | c.3640G>A p.D1214N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs146641651; called by muse, mutect2, varscan2
- RSF1 | c.3610C>T p.R1204* | Nonsense Mutation (SNP) | VAF 19/127 reads (15%) | catalogued as COSV57840228; called by muse, mutect2, varscan2
- RSL1D1 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 86/536 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs772410136, COSV63077793; called by muse, mutect2, varscan2
- RSPH1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs376824155; called by muse, mutect2, varscan2
- RTF2 | c.477+2T>C p.X159_splice | Splice Site (SNP) | VAF 33/202 reads (16%) | catalogued as COSV50128681; called by muse, mutect2, varscan2
- RUBCN | c.830dup p.V278Sfs*16 | Frame Shift Ins (INS) | VAF 14/101 reads (14%) | catalogued as rs745498865; called by mutect2, varscan2
- RXFP3 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.017); catalogued as rs1257769979, COSV57505702; called by muse, mutect2, varscan2
- SAAL1 | c.982dup p.S328Ffs*12 | Frame Shift Ins (INS) | VAF 21/86 reads (24%) | catalogued as rs768235249; called by mutect2, pindel, varscan2
- SACS | c.10249A>C p.S3417R | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV66540264; called by muse, mutect2, varscan2
- SACS | c.6710A>G p.E2237G | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV66533946, COSV66540269; called by muse, mutect2, varscan2
- SCAF1 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV62183197; called by muse, mutect2, varscan2
- SCAP | c.1892G>A p.R631H | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs910327956, COSV55560877; called by muse, mutect2, varscan2
- SCEL | c.1104del p.D369Tfs*28 (on ENST00000349847 / NM_144777.3; = p.D349Tfs*28 on NM_003843.4) | Frame Shift Del (DEL) | VAF 17/128 reads (13%) | catalogued as rs752946345; called by mutect2, pindel, varscan2
- SCN10A | c.4280del p.K1427Sfs*2 | Frame Shift Del (DEL) | VAF 24/126 reads (19%) | catalogued as rs750400627; called by mutect2, varscan2
- SCN2A | c.4635G>T p.M1545I | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV51842334; called by muse, mutect2, varscan2
- SCN4A | c.3500G>A p.C1167Y | Missense Mutation (SNP) | VAF 68/344 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71127009; called by muse, mutect2, varscan2
- SCN4A | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.254); catalogued as COSV71127013; called by muse, mutect2, varscan2
- SCRIB | c.1927G>T p.G643W | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV57582750, COSV57587295; called by muse, mutect2
- SCUBE1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV51811756; called by muse, mutect2, varscan2
- SERPINA9 | c.868A>G p.T290A | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV54075338; called by muse, mutect2
- SERPINF2 | c.277C>A p.L93M | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747689438, COSV60664507; called by muse, mutect2, varscan2
- SFMBT1 | c.2331G>T p.K777N | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV56254179; called by muse, mutect2, varscan2
- SH2D3A | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV55586131; called by muse, mutect2, varscan2
- SH3BP2 | c.1140del p.V381Wfs*8 | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | catalogued as rs759199606; called by mutect2, pindel, varscan2
- SHLD1 | c.209A>C p.N70T | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV57436703; called by muse, mutect2, varscan2
- SKAP2 | c.851A>G p.Q284R | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV61723694; called by muse, mutect2, varscan2
- SLAMF1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs757926113, COSV52499389, COSV52500217; called by muse, mutect2, varscan2
- SLC12A6 | c.1394C>A p.S465Y (on ENST00000354181 / NM_001365088.1; = p.S414Y on NM_005135.2) | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); catalogued as COSV51626231; called by muse, mutect2, varscan2
- SLC13A2 | c.110A>G p.Y37C | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV58995136; called by muse, mutect2, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC27A1 | c.1397A>G p.Y466C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53097592; called by muse, mutect2
- SLC28A2 | c.521T>C p.L174P | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61664130; called by muse, mutect2, varscan2
- SLC35A4 | c.217T>C p.W73R | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV60052510; called by muse, mutect2, varscan2
- SLC39A4 | c.1822G>A p.A608T (on ENST00000301305 / NM_001374839.1; = p.A583T on NM_017767.3) | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.857); catalogued as CD162481, COSV52778966; called by muse, mutect2
- SLC39A4 | c.689G>A p.R230H (on ENST00000301305 / NM_001374839.1; = p.R205H on NM_017767.3) | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs782433578, COSV52778984; called by muse, mutect2, varscan2
- SLC39A6 | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52369329; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 18/83 reads (22%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC41A1 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.157); catalogued as rs760882426, COSV65650565; called by muse, mutect2, varscan2
- SLC44A1 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as COSV58264564; called by muse, mutect2, varscan2
- SLC4A3 | c.3108del p.L1037Sfs*24 | Frame Shift Del (DEL) | VAF 18/99 reads (18%) | catalogued as rs757961785; called by mutect2, pindel, varscan2
- SLC6A7 | c.832del p.Q278Sfs*82 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | catalogued as COSV57939345; called by mutect2, pindel, varscan2
- SLC8A1 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 18/132 reads (14%) | catalogued as COSV60481421, COSV60483015; called by muse, mutect2, varscan2
- SLC8A2 | c.658del p.S220Pfs*12 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs748349403; called by mutect2, pindel
- SLC9A1 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56053550; called by muse, mutect2, varscan2
- SLC9A4 | c.1663G>T p.A555S | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV54834094; called by muse, mutect2, varscan2
- SLC9B1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.491); catalogued as COSV56470331; called by muse, mutect2, varscan2
- SLCO3A1 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs369481876; called by muse, mutect2, varscan2
- SLITRK1 | c.134dup p.F47Lfs*30 | Frame Shift Ins (INS) | VAF 21/133 reads (16%) | catalogued as rs763682501; called by mutect2, varscan2
- SLTM | c.1997G>A p.R666H | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51054189; called by muse, mutect2, varscan2
- SOAT2 | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs775425621, COSV56859578; called by muse, mutect2, varscan2
- SOGA3 | c.2590C>A p.R864S | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as COSV64106669, COSV64109039; called by muse, mutect2, varscan2
- SP7 | c.1151dup p.P385Sfs*40 | Frame Shift Ins (INS) | VAF 11/47 reads (23%) | catalogued as rs749178866; called by mutect2, pindel, varscan2
- SPATA31A1 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 86/521 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1472798149; called by muse, mutect2, varscan2
- SPATA31D1 | c.2966T>G p.V989G | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV61196187; called by muse, mutect2, varscan2
- SPATA5L1 | c.1498G>T p.G500* | Nonsense Mutation (SNP) | VAF 18/81 reads (22%) | catalogued as COSV59744720; called by muse, mutect2, varscan2
- SPEN | c.10922G>A p.R3641H | Missense Mutation (SNP) | VAF 67/305 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as rs367592589; called by muse, mutect2, varscan2
- SPESP1 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV52986490; called by muse, mutect2
- SPNS3 | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.276); catalogued as COSV61070156; called by muse, mutect2, varscan2
- SRPRA | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.138); catalogued as COSV55006689; called by muse, mutect2, varscan2
- SRRM1 | c.2017G>A p.A673T | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1419132510, COSV60477212; called by muse, mutect2, varscan2
- SSRP1 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV53479521; called by muse, mutect2, varscan2
- SSRP1 | c.475T>C p.S159P | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV53479529; called by muse, mutect2, varscan2
- STAB2 | c.6769C>A p.P2257T | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV66339435; called by muse, mutect2, varscan2
- STAG2 | c.1718A>G p.Q573R | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as COSV54359106; called by muse, mutect2, varscan2
- STAT1 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs761876441, COSV63116267; called by muse, mutect2, varscan2
- STAT5B | c.1806G>T p.Q602H | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.251); catalogued as COSV53182676; called by muse, mutect2, varscan2
- STH | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV52240631; called by muse, mutect2, varscan2
- SUPT6H | c.1361T>A p.V454D | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58927541; called by muse, mutect2
- SYNE1 | c.6165A>C p.E2055D (on ENST00000367255 / NM_182961.4; = p.E2062D on NM_033071.3) | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); catalogued as COSV54919898, COSV54925449; called by muse, mutect2, varscan2
- SYNE2 | c.9221A>G p.D3074G | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV59951743; called by muse, mutect2, varscan2
- TAF15 | c.1589dup p.Y531Lfs*56 (on ENST00000605844 / NM_139215.3; = p.Y528Lfs*56 on NM_003487.4) | Frame Shift Ins (INS) | VAF 19/96 reads (20%) | catalogued as rs770087298; called by mutect2, varscan2
- TAF6L | c.1166G>A p.C389Y | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53668617; called by muse, mutect2, varscan2
- TARBP1 | c.2370T>A p.H790Q | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.425); catalogued as COSV50185075; called by muse, mutect2, varscan2
- TASOR2 | c.6992+2T>C p.X2331_splice | Splice Site (SNP) | VAF 9/52 reads (17%) | catalogued as COSV60167585; called by muse, mutect2, varscan2
- TAZ | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as COSV50010359; called by muse, mutect2, varscan2
- TBC1D13 | c.531T>G p.S177R | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.167); catalogued as COSV56354421; called by muse, mutect2
- TBCD | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as rs1567926154, COSV62797246, COSV62801329; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBX6 | c.1057C>A p.P353T | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1427212221, COSV54222008; called by muse, mutect2
- TBXAS1 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54945866; called by muse, mutect2, varscan2
- TBXAS1 | c.1571del p.N524Mfs*29 | Frame Shift Del (DEL) | VAF 18/130 reads (14%) | catalogued as rs748691839; called by mutect2, varscan2
- TCN1 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as rs201160706, COSV57253315, COSV99953158; called by muse, mutect2, varscan2
- TDRD6 | c.3586A>C p.S1196R | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.432); catalogued as COSV60175884; called by muse, mutect2, varscan2
- TEKT5 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as rs773758386, COSV51588645, COSV51589094; called by muse, mutect2, varscan2
- TENM2 | c.2524G>A p.V842I (on ENST00000518659 / NM_001122679.2; = p.V610I on NM_001080428.3) | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.797); catalogued as rs577591482, COSV101319452, COSV69131035; called by muse, mutect2, varscan2
- TENT4A | c.1004C>A p.A335D | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV50095831; called by muse, mutect2, varscan2
- TESPA1 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as rs200958597; called by muse, mutect2, varscan2
- TEX14 | c.2934dup p.I979Hfs*2 (on ENST00000240361 / NM_001201457.2; = p.I973Hfs*2 on NM_031272.5) | Frame Shift Ins (INS) | VAF 31/195 reads (16%) | catalogued as rs1175886165; called by mutect2, pindel, varscan2
- TEX264 | c.59C>T p.T20M | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs375351243; called by muse, mutect2, varscan2
- TFAP2E | c.547T>A p.S183T | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.971); catalogued as COSV64697040; called by muse, mutect2, varscan2
- TFE3 | c.1591G>C p.G531R | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.115); catalogued as COSV59947126; called by muse, mutect2, varscan2
- THBS1 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as rs774720607, COSV52952080; called by muse, mutect2, varscan2
- THSD1 | c.2330C>A p.P777H | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV51628670; called by muse, mutect2, varscan2
- THSD4 | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.838); catalogued as rs779183113, COSV55970786; called by muse, mutect2, varscan2
- TIAM1 | c.4639G>A p.A1547T | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.019); catalogued as rs1481009175, COSV54545610; called by muse, mutect2, varscan2
- TIGD7 | c.488T>C p.I163T | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV51916055; called by muse, mutect2, varscan2
- TLL1 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs749472210, COSV50282527, COSV50282971; called by muse, mutect2, varscan2
- TM9SF4 | c.1015del p.Q339Sfs*4 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs756722453; called by mutect2, pindel, varscan2
- TMEFF2 | c.908del p.K303Rfs*19 | Frame Shift Del (DEL) | VAF 12/79 reads (15%) | catalogued as rs1553506636, COSV55829678; called by mutect2, pindel, varscan2
- TMEM104 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.176); catalogued as rs199563535; called by muse, mutect2, varscan2
- TMEM132D | c.2591A>C p.K864T | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.153); catalogued as COSV67160504, COSV67160536; called by muse, mutect2, varscan2
- TMEM200A | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 7/183 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV51653497; called by muse, mutect2
- TMEM200A | c.1346C>G p.A449G | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV51653530, COSV51654749; called by muse, varscan2
- TMEM201 | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs749348027, COSV61051386; called by mutect2, varscan2
- TMEM26 | c.1016A>G p.Q339R | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV53262732; called by muse, mutect2, varscan2
- TMEM87A | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 14/81 reads (17%) | catalogued as COSV67746955; called by muse, mutect2, varscan2
- TMPO | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as COSV58461779; called by muse, mutect2, varscan2
- TNC | c.118A>G p.T40A | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV60785218; called by muse, mutect2, varscan2
- TNFAIP3 | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.914); catalogued as COSV52799039; called by muse, mutect2, varscan2
- TNFRSF13B | c.693C>A p.S231R | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CM119283, COSV55425457; called by muse, mutect2, varscan2
- TNPO2 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs1291299846, COSV63508398; called by muse, mutect2, varscan2
- TNS2 | c.1095+2T>C p.X365_splice (on ENST00000314250 / NM_170754.4; = p.X375_splice on NM_015319.2) | Splice Site (SNP) | VAF 12/56 reads (21%) | catalogued as COSV58577778; called by muse, mutect2, varscan2
- TOP2A | c.4303del p.R1435Gfs*13 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as rs758129598; called by mutect2, pindel, varscan2
- TRAPPC10 | c.1160G>T p.G387V | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV52377599; called by muse, mutect2, varscan2
- TRIM46 | c.1363dup p.H455Pfs*11 | Frame Shift Ins (INS) | VAF 13/48 reads (27%) | catalogued as rs760983049; called by mutect2, varscan2
- TRIM56 | c.1423A>C p.S475R | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.987); catalogued as COSV60159081; called by muse, mutect2, varscan2
- TRIM6 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs1238156687, COSV53475234; called by muse, mutect2, varscan2
- TRPA1 | c.2017del p.T673Hfs*23 | Frame Shift Del (DEL) | VAF 19/152 reads (13%) | catalogued as rs748693374; called by mutect2, pindel, varscan2
- TRPC6 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 33/181 reads (18%) | catalogued as COSV60255073; called by muse, mutect2, varscan2
- TRPV5 | c.2164G>A p.D722N | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV54686165; called by muse, mutect2, varscan2
- TSHZ2 | c.3032T>G p.L1011R | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61588919; called by muse, mutect2, varscan2
- TSPAN15 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0.015); catalogued as rs371948856; called by muse, mutect2, varscan2
- TSR2 | c.361A>T p.K121* | Nonsense Mutation (SNP) | VAF 20/152 reads (13%) | catalogued as COSV64308758; called by muse, mutect2, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | catalogued as rs756650873; called by mutect2, varscan2
- TTC39B | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.883); catalogued as rs192520168, COSV52610703, COSV52616854; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 15/67 reads (22%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.44006T>A p.V14669D (on ENST00000591111; = p.V7245D on NM_003319.4) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | PolyPhen benign (0.075); catalogued as COSV60081337; called by muse, mutect2, varscan2
- TTN | c.36385A>G p.T12129A (on ENST00000591111; = p.T4705A on NM_003319.4) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | PolyPhen benign (0.024); catalogued as COSV60081376; called by muse, mutect2, varscan2
- TTN | c.17300G>A p.C5767Y (on ENST00000591111; = p.C4840Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | PolyPhen possibly damaging (0.884); catalogued as COSV60081414; called by muse, mutect2, varscan2
- TTN | c.11310A>C p.E3770D (on ENST00000591111; = p.E3724D on NM_003319.4) | Missense Mutation (SNP) | VAF 19/128 reads (15%) | catalogued as COSV59861813; called by muse, mutect2, varscan2
- TTN | c.5468C>A p.A1823D (on ENST00000591111; = p.A1777D on NM_003319.4) | Missense Mutation (SNP) | VAF 28/170 reads (16%) | PolyPhen possibly damaging (0.836); catalogued as COSV60081455; called by muse, varscan2
- TUBB6 | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1222273821, COSV52314606; called by muse, mutect2, varscan2
- TUBGCP5 | c.2136del p.D713Ifs*5 | Frame Shift Del (DEL) | VAF 18/113 reads (16%) | catalogued as rs1432092958; called by mutect2, pindel, varscan2
- TULP1 | c.941A>G p.K314R | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV57692671; called by muse, mutect2
- TULP4 | c.1082C>T p.S361L | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV65575888; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as rs760251146; called by mutect2, varscan2
- TWNK | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 8/154 reads (5%) | catalogued as rs1359549423, COSV52968358; called by muse, mutect2
- UACA | c.2353T>A p.L785M | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59856047; called by muse, mutect2, varscan2
- UBA7 | c.178A>G p.T60A | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as COSV61092313; called by muse, mutect2, varscan2
- UBE2W | c.257G>T p.S86I | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV62475865; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3661A>G p.T1221A | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV54437786; called by muse, mutect2
- UNC13B | c.3205G>A p.V1069M | Missense Mutation (SNP) | VAF 70/382 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs140663072; called by muse, varscan2
- UNC45B | c.1551G>A p.W517* | Nonsense Mutation (SNP) | VAF 38/179 reads (21%) | catalogued as rs1237412903, COSV52096028; called by muse, mutect2, varscan2
- UNC5D | c.1226A>G p.D409G | Missense Mutation (SNP) | VAF 45/337 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.049); catalogued as COSV54796672; called by muse, mutect2, varscan2
479 further variants in this file (189 protein-altering or splice-affecting, 269 silent, 21 other) are not listed here.
